Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-A9RC, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-A9RC-01A (Primary Tumor).

[page 1 of 2]
Lab No:

Sender:

Location:

Taken :

Received:

Status:

PRINTED FROM ENQUIRY

SPECIMEN

Bladder and prostate.

CLINICAL DETAILS

Cystectomy.

MACROSCOPY

ICD.O.3

Carcinoma, urothelial NOS 8120/3

Site Bladder, lateral wall c67.2

9/5/14

A cystoprostatectomy specimen comprising bladder (measuring 78 mm supero-inferiorly x 68 mm transversely x 62mm antero-posteriorly), prostate (measuring 38 mm supero-inferiorly x 54 mm transversely x-45 mm antero-posteriorly), perivesicular fat up to 45 mm in depth and right and left ureteric stumps each approx. 35 mm long.

On opening the bladder, there is a tumour on the left lateral wall extending onto the dome measuring 42 mm maximum dimension and 18 mm maximum depth. The extent of invasion cannot be ascertained. The distance to left pelvic surgical resection margin is approximately 12 mm. The background bladder mucosa appears normal. The prostate shows some nodularity. A lymph node measuring 20 mm in maximum dimension is located deep to the tumour.

Please note

The resection margins and lymph nodes associated with this surgical procedure have been processed as

MICROSCOPY

Please note

The following report includes the findings from the resection margins and lymph nodes processed as

T1» tumour in the bladder is a poorly differentiated (Grade 3) urothelial carcinoma. It arises from the surface and invades through muscle to reach just beyond the muscularis propria into the extravesical fat. No unequivocal

[page 2 of 2]
evidence of lymphovascular invasion is seen. The background bladder urothelium shows a focus of cystitis cystica but no metaplasia, dysplasia or intraepithelial neoplasia.

The left and right ureteric resection margins show no evidence of tumour and are lined by normal urothelium. The urethral resection margin is free of tumour.

The closest peripheral surgical margin lies 11 mm on the left.

The left prostate gland contains extensive prostatic microacinar adenocarcinoma, extending from the apex to the middle of the gland. A small focus is present in the right apex. There is perineural involvement within the capsule but no evidence of extracapsular tumour. The prostatic adenocarcinoma has been fully excised with no evidence of tumour at intraprostatic or extraprostatic surgical resection margins. The urethral resection margin shows no prostatic or urothelial carcinoma.

A total of 21 lymph nodes have been identified (3 x perivesical; 1 x right ext. iliac; 1 x left obturator; 2 x left ext. iliac; 5 x left int. iliac; 3 x right int. iliac; 0 x left common iliac). none of which contain metastatic urothelial carcinoma. However, two nodes show metastatic prostatic adenocarcinoma (1 out of 3 perivesical, near right ureter; 1 out of 5 left int. iliac).

SUMMARY

Bladder - urothelial carcinoma, Grade 3 pT3a pN0 pMx.

Prostate - adenocarcinoma, bilateral, Gleason grade 4 + 3 = 7 (tertiary pattern 5) pT2c pN1 pMx

Pathologists:

DR PATHOLOGIST
DR , CONSULTANT

Source: NCI Genomic Data Commons file 40abbfaa-3500-42e9-9817-ce9e9f555f87 (TCGA-ZF-A9RC.B7DD19FB-FF13-44CB-88FF-B42A6E20962B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).